HCMI case HCM-CSHL-0773-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6135448b-e32a-4836-8355-b00036503577

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1946; Vital status: Alive.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 62.3 years (22,742 days); AJCC staging edition: 6th; AJCC clinical stage: Stage IA; AJCC pathologic T: T1; AJCC pathologic N: N0 (i-); AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Tumor grade: G2; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 3 days.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 54 days; Days to treatment end: 1,526 days (4.2 years).
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,545 days (4.2 years); Days to treatment end: 1,880 days (5.1 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 3,794 days (10.4 years); Days to treatment end: 3,808 days (10.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 3,817 days (10.5 years); Days to treatment end: 3,979 days (10.9 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 3,979 days (10.9 years); Days to treatment end: 4,132 days (11.3 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 4,141 days (11.3 years); Days to treatment end: 4,194 days (11.5 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Eribulin Mesylate; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 4,227 days (11.6 years); Days to treatment end: 4,254 days (11.6 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Sacituzumab Govitecan; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 4,305 days (11.8 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Everolimus; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 4,420 days (12.1 years); Days to treatment end: 4,467 days (12.2 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 4,507 days (12.3 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 4,638 days (12.7 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Treatment intent type: Adjuvant; Initial disease status: Residual Disease.
   Recorded as not given: neoadjuvant treatment (type not reported); prevention Hormone Therapy.
2. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/6; ICD-10 code: C79.89; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: metastasis; Age at diagnosis: 72.6 years (26,527 days); Days to diagnosis: 3,785 days (10.4 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Anastrozole; Treatment intent type: Maintenance Therapy; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Letrozole; Treatment intent type: Maintenance Therapy; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Nab-paclitaxel; Treatment intent type: Maintenance Therapy; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Xeloda; Treatment intent type: Maintenance Therapy; Treatment outcome: Treatment Ongoing.
   Recorded as not given: prevention Hormone Therapy.

Follow-up (2 entries)
- Days to follow up: 4,660 days (12.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contacts recording only the day: day 0, day 4,569.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.
- ESR1 (IHC): 1; Specialized molecular test: Allred score.
- ESR1 (IHC): 8; Specialized molecular test: Allred score.
- PGR (IHC): Negative.
- PGR (IHC): Positive.
- Test (Other): Low; Specialized molecular test: Oncotype.

Other clinical attributes
- Day 0: Menopause status: Postmenopausal.
- Timepoint category: Initial Diagnosis; Weight: 81.6 kg; Height: 165.1 cm; BMI: 30.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-CSHL-0773-C50-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0773-C50-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
